MMRF case MMRF_2410 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/c27c68d8-dc03-4be8-8254-e43cfc68e2f1

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 60 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 60.7 years (22,179 days); ISS stage: I; Days to last known disease status: 85 days; Days to last follow up: 85 days.
   Treatment given: Therapeutic agents: Bortezomib + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 64 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 75 days.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -9 (ECOG 0): M Protein 2.92 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.79 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.01 mg/dL; Immunoglobulin G 4.35 g/L; Immunoglobulin A 31.2 g/L; Immunoglobulin M 0.31 g/L; Beta 2 Microglobulin 2.53 µg/mL; Lactate Dehydrogenase 2.45 µkat/L; Hemoglobin 8.43 mmol/L; Leukocytes 8.2 ×10⁹/L; Absolute Neutrophil 4.3 ×10⁹/L; Platelets 236 ×10⁹/L; Creatinine 73.4 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.58 mmol/L; Albumin 44 g/L; Total Protein 9.4 g/dL; Glucose 4.35 mmol/L; C-Reactive Protein 0.09 mg/dL.
- Day 85 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.945 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.346 mg/dL; Immunoglobulin G 4.63 g/L; Immunoglobulin A 1.41 g/L; Immunoglobulin M 0.25 g/L; Lactate Dehydrogenase 2.13 µkat/L; Hemoglobin 9.3 mmol/L; Leukocytes 8.4 ×10⁹/L; Absolute Neutrophil 5.1 ×10⁹/L; Platelets 143 ×10⁹/L; Creatinine 57.5 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.28 mmol/L; Albumin 38 g/L; Total Protein 6.2 g/dL; Glucose 5.34 mmol/L.

Other clinical attributes
- Day -9: Weight: 80 kg; Height: 175 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_2410_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -9 days.
- Sample MMRF_2410_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -9 days.
